Somatic mutation profile of tumor specimen 0DFRTU from CCDI case PBBSJY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Desmoplastic nodular medulloblastoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 1.6 years (568 days).
Specimen 0DFRTU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8467bf97-353d-47d1-a593-40f75c8e5aab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFRTV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a592f305-f945-48b4-bdd0-e4ccd3c5ca48

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 1, 5'UTR 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 80/1718 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- SUFU | c.833_842del p.L278Pfs*32 | Frame Shift Del (DEL) | VAF 442/494 reads (89%) | called by mutect2, varscan2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 18/374 reads (5%) | called by muse, mutect2
- RNF146 | c.978A>T p.S326= (on ENST00000368314 / NM_001242850.2; = p.S325= on NM_030963.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 84/1614 reads (5%) | catalogued as rs770171920; called by muse, mutect2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 11/93 reads (12%) | catalogued as rs1262556378; called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 36/284 reads (13%) | called by muse, varscan2
